Somatic mutation profile of tumor specimen 0DQOF3 from CCDI case PBCFFY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.4 years (1,610 days).
Specimen 0DQOF3: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8a3f60-d880-4c0a-b4a8-23c1ff9e94e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOEW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de3ef4c0-1282-4d9f-9fbc-6251c574ab47

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Intron 3, Frame Shift Del 1, Nonsense Mutation 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 528/544 reads (97%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRAMD4 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 366/830 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.618); catalogued as rs200706485, COSV100730704; called by muse, mutect2, varscan2
- NBPF1 | c.1393G>C p.A465P | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99845200; called by muse, mutect2, varscan2
- RPUSD1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143488932; called by muse, mutect2, varscan2
- URI1 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs758579896; called by muse, mutect2, varscan2
- ALS2 | c.3902G>A p.W1301* | Nonsense Mutation (SNP) | VAF 24/826 reads (3%) | called by muse, mutect2
- C1QTNF6 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 272/633 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- FRS2 | c.32A>G p.D11G | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MICU3 | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 111/605 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MRC1 | c.3172G>T p.G1058C | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PAPPA2 | c.3987del p.H1330Tfs*14 | Frame Shift Del (DEL) | VAF 292/707 reads (41%) | called by mutect2, pindel, varscan2
- PKN1 | c.134_135insTTGGGA p.R44_E45insDW | In Frame Ins (INS) | VAF 116/421 reads (28%) | called by mutect2, pindel, varscan2
- TDRD12 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 32/712 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2
- ACAP3 | c.2289C>T p.H763= | Silent (SNP) | VAF 210/498 reads (42%) | catalogued as rs749256892; called by muse, varscan2
- ATP12A | c.702G>C p.T234= | Silent (SNP) | VAF 399/647 reads (62%) | catalogued as rs755329459, COSV99517091; called by muse, mutect2, varscan2
- ELAVL3 | c.762G>A p.S254= | Silent (SNP) | VAF 86/277 reads (31%) | catalogued as rs567829899, COSV52954046; called by muse, mutect2, varscan2
- KRT81 | c.1362C>T p.S454= | Silent (SNP) | VAF 166/371 reads (45%) | catalogued as rs1382298736; called by muse, mutect2, varscan2
- PCDHA1 | c.1944G>C p.L648= | Silent (SNP) | VAF 356/751 reads (47%) | called by muse, mutect2, varscan2
- RRH | c.354C>T p.V118= | Silent (SNP) | VAF 259/548 reads (47%) | catalogued as rs373432160; called by muse, mutect2, varscan2
- S1PR4 | c.1089C>T p.G363= | Silent (SNP) | VAF 200/621 reads (32%) | called by muse, mutect2, varscan2
- TBC1D9B | c.678C>A p.L226= | Silent (SNP) | VAF 282/558 reads (51%) | called by muse, mutect2, varscan2
- CFAP61 | c.-37+71G>A | Intron (SNP) | VAF 376/1304 reads (29%) | called by muse, mutect2
- PAK5 | c.*63A>T | 3'UTR (SNP) | VAF 150/472 reads (32%) | called by muse, mutect2, varscan2
- SMAD7 | c.668-120del | Intron (DEL) | VAF 160/428 reads (37%) | called by mutect2, pindel, varscan2
- SPTLC2 | c.851-68_851-67del | Intron (DEL) | VAF 63/154 reads (41%) | called by pindel, varscan2
